Gene-level copy-number profile of tumor specimen TCGA-GU-AATQ-01A from TCGA case TCGA-GU-AATQ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 69.0 years (25,185 days).
Specimen TCGA-GU-AATQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.e573882e-40ef-4e4a-97b2-5406b98cbd48.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GU-AATQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7a05e11f-911f-42e9-8078-db4ba6987b46

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 288; copy number 2: 12,044; copy number 3: 25,081; copy number 4: 16,213; copy number 5: 3,281; copy number 6: 1,532; copy number 7: 1,213; copy number 8: 35; copy number 15: 71.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GU-AATQ-01A-11D-A390-01): tumor purity 0.75, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:6,490,460–6,805,479, 3 genes (within-gene range 0–2): AC069277.1, GRM7-AS3, AC069277.2.
- chr3:6,773,037–6,894,022, 2 genes: MRPS36P1, GRM7-AS2.
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–2): MIR31HG.
- chr9:21,480,839–25,089,151, 41 genes: IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.
- chr9:137,877,782–138,203,325, 6 genes (within-gene range 0–4): CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,319 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,140,391–121,580,524, 71 genes, copy number 15 (within-gene range 3–15) (broad region; genes not listed).
- chr1:148,739,379–149,754,710, 28 genes, copy number 7 (within-gene range 6–7): RNU6-1171P, NUDT4B, SEC22B3P, AC245389.1, PDE4DIP, RN7SKP88, RNU2-38P, AC239802.1, AC239802.2, AC239804.2, RNVU1-24, AC245297.3, AC245297.1, AC245297.2, 7SK, SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19, PPIAL4C, LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P, AC243772.3, RNU1-68P, AC243772.1.
- chr3:130,212,823–188,890,671, 955 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr3:195,996,262–198,222,513, 86 genes, copy number 7 (broad region; genes not listed).
- chr8:81,275,399–87,615,219, 94 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr9:80,782,338–82,780,194, 27 genes, copy number 7: RPS19P6, AL138749.1, RPS20P25, AL161727.1, TLE1, AL591368.1, RNU6-1035P, RNA5SP287, AL158154.1, SPATA31D5P, AL158154.2, SPATA31D4, AL158154.3, SPATA31D3, SPATA31D2P, AL162726.3, SPATA31D1, SPATA31B1P, DDX10P2, AL158047.1, AL162726.1, MTCO3P40, AL162726.2, AL162726.4, AL356490.1, AL353774.1, RPS6P12.
- chr11:56,165,500–56,878,078, 55 genes, copy number 7: OR5J7P, OR5J2, OR8V1P, AC022882.1, OR8J2, OR5T2, OR5T3, OR5T1, OR8H1, OR8I1P, OR8K3, FAM8A2P, OR8K2P, OR8K1, OR8J1, RPL5P29, OR8U1, OR8L1P, OR5AL2P, OR5AL1, OR5R1, OR5M4P, AP002512.3, OR5M9, OR5M3, OR5M2P, OR5M8, AP002512.1, OR5M7P, AP002512.2, OR5M6P, OR5M5P, OR5M11, OR5M10, OR5M13P, OR5M1, OR5AM1P, OR5M12P, OR5AP1P, OR5AP2, OR5AR1, OR2AH1P, TMEM230P2, OR9G1, AP001803.1, OR9G3P, OR9G4, MIR6128, AP001803.10, OR9G2P, OR5G1P, OR5G4P, OR5G5P, OR5G3, LINC02735.
- chr11:57,917,297–58,005,705, 3 genes, copy number 7: OR5AZ1P, OR5BD1P, CYCSP26.

Autosomal genes at a single copy (total copy number 1): 288. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
